Somatic mutation profile of tumor specimen TCGA-HT-7483-01A (aliquot TCGA-HT-7483-01A-11D-2024-08) from TCGA case TCGA-HT-7483, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 14.4 years (5,267 days).
Specimen TCGA-HT-7483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d0ae776-c6fe-4124-baf6-44e70ff5c8e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7483-10A (Blood Derived Normal), aliquot TCGA-HT-7483-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b0491d-bbd3-48a8-9d1a-333a911a0ae0

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.1579G>A p.E527K (on ENST00000490131; = p.E604K on NM_000388.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs104893712, CM030375, COSV56134726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 26/81 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 57/70 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as rs1214490669, COSV64645713, COSV64676633; called by muse, mutect2, varscan2
- CDR2 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV51675574; called by muse, mutect2, varscan2
- FLAD1 | c.1612A>G p.I538V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.657); catalogued as COSV52696179; called by muse, mutect2, varscan2
- HIVEP3 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV56009059; called by muse, mutect2, varscan2
- KCNH8 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100108399, COSV60458877; called by muse, mutect2, varscan2
- PACS1 | c.1262A>G p.K421R | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1477937129, COSV57696908; called by muse, mutect2
- SEPTIN4 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs987143150, COSV58727363; called by muse, mutect2, varscan2
- TLR3 | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs1253689203, COSV57167859; called by muse, varscan2
- SRSF10 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ABHD16B | c.714C>T p.P238= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1165004388, COSV53861860, COSV99410634; called by muse, mutect2, varscan2
- ADRA1D | c.1462C>A p.R488= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV65240414; called by muse, mutect2, varscan2
- FGD6 | c.153A>C p.A51= | Silent (SNP) | VAF 114/304 reads (38%) | catalogued as COSV59691303; called by muse, mutect2, varscan2
